Somatic mutation profile of tumor specimen 0DKRD1 from CCDI case PBBYEE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,327 days).
Specimen 0DKRD1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9b609a7-a4a8-4512-a065-4dc02af8d10f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f178f39-654a-4002-9657-c16f60462902

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRAID | c.657G>A p.M219I (on ENST00000611786; = p.M106I on NM_016085.5) | Missense Mutation (SNP) | VAF 34/816 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- CPA4 | c.1038G>A p.S346= | Silent (SNP) | VAF 50/486 reads (10%) | catalogued as rs775082970, COSV55983714; called by muse, mutect2, varscan2
- TRMT12 | c.558T>A p.T186= | Silent (SNP) | VAF 24/664 reads (4%) | called by muse, mutect2
